Somatic mutation profile of tumor specimen TCGA-18-5592-01A (aliquot TCGA-18-5592-01A-01D-1632-08) from TCGA case TCGA-18-5592, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57.5 years (21,020 days).
Specimen TCGA-18-5592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 473eb805-d5a1-4313-a740-d373dba07218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-5592-11A (Solid Tissue Normal), aliquot TCGA-18-5592-11A-11D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff524f0d-ecc1-4981-b449-1c0a80d12b48

The open-access MAF lists 304 somatic variants for this specimen: 244 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 53, Nonsense Mutation 10, Frame Shift Del 10, Splice Site 5, RNA 3, Splice Region 2, Nonstop Mutation 2, Intron 1, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 62/148 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960256, COSV67960411, COSV67962235; called by muse, mutect2, varscan2
- RHAG | c.1067+1G>A p.X356_splice | Splice Site (SNP) | VAF 29/98 reads (30%) | catalogued as rs1562012617, CS982347, COSV57703785; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 97/121 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.760T>A p.S254T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.092); catalogued as COSV52705607; called by muse, mutect2
- ABCF3 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as rs757145557, COSV53047679; called by muse, mutect2, varscan2
- AC100868.1 | c.1670G>T p.C557F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51840785; called by muse, mutect2, varscan2
- ACTG2 | c.1087T>A p.Y363N | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61828046; called by muse, mutect2, varscan2
- ADGRE1 | c.1447T>A p.F483I | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51674386; called by muse, mutect2, varscan2
- ADGRV1 | c.12868C>T p.R4290C | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775861115, COSV67982880; called by muse, mutect2, varscan2
- ANKRD22 | c.156T>G p.H52Q | Missense Mutation (SNP) | VAF 165/272 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV64236253; called by muse, mutect2, varscan2
- ANO3 | c.1449del p.T484Qfs*14 | Frame Shift Del (DEL) | VAF 69/168 reads (41%) | catalogued as COSV99883882; called by mutect2, pindel, varscan2
- ARHGEF7 | c.1187T>C p.I396T (on ENST00000375741 / NM_001113511.2; = p.I218T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54539558; called by muse, mutect2, varscan2
- ATP10B | c.1826C>A p.P609H | Missense Mutation (SNP) | VAF 157/248 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV59148116; called by muse, mutect2, varscan2
- ATP11A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52109532; called by muse, mutect2, varscan2
- BCAS2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.112); catalogued as rs767359809, COSV65767240, COSV65767380; called by muse, mutect2, varscan2
- BRINP3 | c.2282C>G p.T761R | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV66519346, COSV66532947; called by muse, mutect2, varscan2
- CAMKMT | c.762G>T p.R254S | Missense Mutation (SNP) | VAF 25/465 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs764125751, COSV65924805; called by muse, mutect2
- CAND2 | c.1075A>T p.I359F (on ENST00000456430 / NM_001162499.2; = p.I266F on NM_012298.3) | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV55988912; called by muse, mutect2, varscan2
- CARS1 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 111/167 reads (66%) | catalogued as COSV53452841; called by muse, mutect2, varscan2
- CCDC50 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66667646; called by muse, mutect2, varscan2
- CCDC80 | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV52816060; called by muse, mutect2, varscan2
- CCNK | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 154/348 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV66274543; called by muse, mutect2, varscan2
- CD300E | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60790275; called by muse, mutect2, varscan2
- CDC42BPA | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV62008692; called by muse, mutect2
- CDC42BPG | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV61346661; called by muse, mutect2
- CDH10 | c.1299C>A p.N433K | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV52576804; called by muse, mutect2, varscan2
- CDH10 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 158/171 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52576813; called by muse, mutect2, varscan2
- CDH7 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100542916, COSV59884052; called by muse, mutect2, varscan2
- CDX2 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV66829331; called by muse, mutect2, varscan2
- CEACAM19 | c.348C>G p.D116E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62551916; called by muse, mutect2
- CFAP57 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 83/128 reads (65%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs376583075; called by muse, mutect2, varscan2
- CLDN1 | c.636A>C p.*212Cext*10 | Nonstop Mutation (SNP) | VAF 44/394 reads (11%) | catalogued as COSV55043750; called by muse, mutect2, varscan2
- CLEC4M | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370560578, COSV50217617; called by muse, mutect2, varscan2
- COASY | c.1249A>T p.K417* | Nonsense Mutation (SNP) | VAF 126/268 reads (47%) | catalogued as COSV55898147; called by muse, mutect2, varscan2
- COL22A1 | c.3454G>T p.A1152S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.092); catalogued as COSV57331446; called by muse, mutect2, varscan2
- COL22A1 | c.2877A>T p.E959D | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.474); catalogued as rs535667291, COSV57331456; called by muse, mutect2, varscan2
- COL3A1 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV58585428; called by muse, mutect2, varscan2
- COL4A2 | c.3088G>T p.G1030C | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64626985; called by muse, mutect2, varscan2
- COL4A4 | c.3928G>A p.G1310R | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61630449; called by muse, mutect2, varscan2
- COL4A4 | c.1978G>T p.G660C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951795075, COSV61631116; called by mutect2, varscan2
- CORO6 | c.754-1G>A p.X252_splice | Splice Site (SNP) | VAF 43/212 reads (20%) | catalogued as COSV61470563; called by muse, mutect2, varscan2
- CPS1 | c.2191G>T p.G731C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51806653; called by muse, mutect2, varscan2
- CPS1 | c.3245A>C p.Q1082P | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.483); catalogued as COSV51806669; called by muse, mutect2, varscan2
- CRB1 | c.2707C>A p.H903N | Missense Mutation (SNP) | VAF 286/444 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV66329425; called by muse, mutect2, varscan2
- CSMD3 | c.7539G>T p.Q2513H (on ENST00000297405 / NM_001363185.1; = p.Q2409H on NM_052900.3) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV52148038; called by muse, mutect2, varscan2
- CSMD3 | c.1558G>T p.G520C (on ENST00000297405 / NM_001363185.1; = p.G416C on NM_052900.3) | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52148084; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 82/108 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- CUL3 | c.1378-1G>A p.X460_splice | Splice Site (SNP) | VAF 131/326 reads (40%) | catalogued as COSV52362106, COSV52363563; called by muse, mutect2, varscan2
- CYP4F12 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757430082, COSV61173217; called by muse, mutect2, varscan2
- DCDC1 | c.2516T>C p.L839P | Missense Mutation (SNP) | VAF 102/373 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV60839156; called by muse, mutect2, varscan2
- DDX27 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65629428; called by muse, mutect2, varscan2
- DDX3X | c.1057G>T p.D353Y (on ENST00000399959; = p.D354Y on NM_001356.5) | Missense Mutation (SNP) | VAF 112/140 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863073, COSV67863895, COSV67863993; called by muse, mutect2, varscan2
- DNAH7 | c.10217G>A p.G3406E | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56759131; called by muse, mutect2, varscan2
- DNAH7 | c.2780C>A p.T927K | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56759141; called by muse, mutect2, varscan2
- DNM3 | c.1738G>A p.D580N (on ENST00000355305 / NM_001350206.2; = p.D570N on NM_015569.5) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV62455999; called by muse, mutect2
- DRD3 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 21/686 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55681902; called by muse, mutect2
- DST | c.12224T>G p.I4075S (on ENST00000361203 / NM_001374722.1; = p.I1663S on NM_015548.5) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV55007729, COSV55016736; called by muse, mutect2, varscan2
- DST | c.2039T>A p.L680* (on ENST00000361203 / NM_001374722.1; = p.L354* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 117/299 reads (39%) | catalogued as COSV55007744; called by muse, mutect2, varscan2
- EML5 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61344081; called by muse, mutect2, varscan2
- ERBB4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.307); catalogued as COSV53520330; called by muse, mutect2, varscan2
- F2RL2 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.191); catalogued as COSV56970380; called by muse, mutect2, varscan2
- F7 | c.1385G>C p.R462P | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV60645722; called by muse, mutect2, varscan2
- FADS3 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53877925, COSV53879531; called by muse, mutect2, varscan2
- FAM135B | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV52706750; called by muse, mutect2, varscan2
- FAM50A | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50130860, COSV50130951; called by muse, mutect2, varscan2
- FBLN2 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 98/139 reads (71%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.625); catalogued as COSV55482895; called by muse, mutect2, varscan2
- FCAR | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs587636812, COSV62029195; called by muse, mutect2, varscan2
- FLG | c.7363T>A p.S2455T | Missense Mutation (SNP) | VAF 307/1425 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.078); catalogued as COSV64240035; called by muse, mutect2, varscan2
- FLT1 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.439); catalogued as COSV56724461; called by muse, mutect2, varscan2
- FLT3 | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54049899, COSV54057735; called by muse, mutect2, varscan2
- FMN2 | c.4090A>G p.R1364G | Missense Mutation (SNP) | VAF 112/211 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60425935; called by muse, mutect2, varscan2
- FOLH1 | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57047727; called by muse, mutect2, varscan2
- FREM2 | c.8278C>G p.P2760A | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV54834162; called by muse, mutect2, varscan2
- FZD7 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53808971; called by muse, mutect2, varscan2
- GABRB2 | c.1012C>A p.Q338K | Missense Mutation (SNP) | VAF 114/171 reads (67%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.871); catalogued as COSV50906702; called by muse, mutect2, varscan2
- GALNT17 | c.423-1G>T p.X141_splice | Splice Site (SNP) | VAF 106/206 reads (51%) | catalogued as COSV61156192; called by muse, mutect2, varscan2
- GARRE1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV55098227; called by muse, mutect2, varscan2
- GHDC | c.188A>C p.H63P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV56987565; called by muse, mutect2, varscan2
- GLB1L3 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68392562; called by muse, mutect2, varscan2
- GPR63 | c.609G>T p.W203C | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57739381, COSV57740691; called by muse, mutect2, varscan2
- GSTA2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.792); catalogued as COSV72414836; called by muse, mutect2, varscan2
- GUCY1A2 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV56483271; called by muse, mutect2, varscan2
- H2BW1 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV54219971, COSV54220810; called by muse, mutect2, varscan2
- HAND2 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64018006; called by muse, mutect2, varscan2
- HERC2 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55314709, COSV55317576; called by muse, mutect2, varscan2
- HIF3A | c.1237G>T p.D413Y (on ENST00000377670 / NM_152795.4; = p.D344Y on NM_022462.4) | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52197208; called by muse, mutect2, varscan2
- HIF3A | c.1238A>T p.D413V (on ENST00000377670 / NM_152795.4; = p.D344V on NM_022462.4) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as COSV52197238; called by muse, mutect2, varscan2
- HSPBAP1 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs765608517, COSV60241881; called by muse, mutect2, varscan2
- IFI16 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV55532876; called by muse, mutect2
- IMPG2 | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs762262011, COSV51976251; called by muse, mutect2, varscan2
- IQSEC3 | c.552T>A p.P184= | Splice Region (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100406863; called by muse, mutect2, varscan2
- ITGA4 | c.2159A>G p.H720R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV67896836; called by muse, mutect2, varscan2
- ITGB2 | c.1658T>C p.I553T (on ENST00000302347; = p.I529T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs1568881823, COSV56609264; called by muse, mutect2, varscan2
- KANK2 | c.1674C>A p.S558R (on ENST00000586659 / NM_001379562.1; = p.S566R on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV62007441; called by muse, mutect2, varscan2
- KAT6A | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs753999434, COSV55904980; called by muse, mutect2, varscan2
- KCNQ2 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV60433026; called by muse, mutect2, varscan2
- KCTD16 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101568876, COSV72578143; called by muse, mutect2, varscan2
- KCTD3 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV52065716; called by muse, mutect2, varscan2
- KCTD8 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63587653; called by muse, mutect2, varscan2
- KIAA1217 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64603779; called by muse, mutect2, varscan2
- KIAA1328 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54451315; called by muse, mutect2, varscan2
- KIAA1755 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1057248890, COSV54075400; called by muse, mutect2, varscan2
- KIF18A | c.2456C>G p.S819C | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54182250; called by muse, mutect2, varscan2
- KIRREL2 | c.1045G>C p.G349R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV52875471; called by muse, mutect2, varscan2
- KLHL11 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1332070383, COSV59861761; called by muse, mutect2, varscan2
- KLHL23 | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); catalogued as rs759110549, COSV55866597; called by muse, mutect2, varscan2
- LAIR1 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778685179, COSV57307057; called by muse, mutect2, varscan2
- LAMA1 | c.3576G>T p.E1192D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV67534947; called by muse, mutect2
- LAMA2 | c.5896G>T p.D1966Y | Missense Mutation (SNP) | VAF 95/141 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV70344189, COSV70350934; called by muse, mutect2, varscan2
- LARGE1 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.084); catalogued as COSV61660075; called by muse, mutect2, varscan2
- LCP1 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV59940407; called by muse, mutect2, varscan2
- LIN37 | c.658A>T p.R220W | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50000416; called by muse, mutect2
- LPXN | c.12A>C p.L4F | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60158279; called by muse, mutect2, varscan2
- LRRC6 | c.725A>G p.N242S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51540220; called by muse, mutect2, varscan2
- MAP3K21 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 143/243 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV64041460; called by muse, varscan2
- MAP3K7 | c.1777G>A p.E593K (on ENST00000369329 / NM_145331.3; = p.E566K on NM_003188.4) | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV65223612; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2236G>T p.G746C | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV51718684; called by muse, mutect2, varscan2
- MED12L | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs1173563815, COSV56374936; called by muse, mutect2, varscan2
- MED12L | c.4531G>A p.A1511T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV56374948; called by muse, mutect2, varscan2
- MED13 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101180956, COSV67262904; called by muse, mutect2, varscan2
- MGLL | c.28A>T p.T10S (on ENST00000398104 / NM_001003794.2; = p.T20S on NM_007283.6) | Missense Mutation (SNP) | VAF 202/256 reads (79%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV54024193; called by muse, mutect2, varscan2
- MIA | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54571181; called by muse, mutect2, varscan2
- MIOS | c.804A>T p.K268N | Missense Mutation (SNP) | VAF 189/224 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV60767918; called by muse, mutect2, varscan2
- MUC16 | c.19846C>G p.P6616A | Missense Mutation (SNP) | VAF 141/312 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.235); catalogued as COSV67458238; called by muse, mutect2, varscan2
- MUC16 | c.16234A>T p.T5412S | Missense Mutation (SNP) | VAF 357/726 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.047); catalogued as rs780822715, COSV67458254; called by muse, mutect2, varscan2
- MYH14 | c.5245C>T p.R1749C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778870714, COSV51814418; called by muse, mutect2, varscan2
- MYH2 | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV55435384; called by muse, mutect2, varscan2
- MYH3 | c.398C>G p.P133R | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56863391; called by muse, mutect2, varscan2
- MYO3A | c.1961G>T p.C654F | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56326355; called by muse, mutect2, varscan2
- NAALADL2 | c.1424G>C p.R475P | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV69155077, COSV69161223; called by muse, mutect2, varscan2
- NAV2 | c.1402G>A p.A468T (on ENST00000396087 / NM_001244963.2; = p.A445T on NM_145117.5) | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs143571074, COSV62319823; called by muse, mutect2
- NCAM2 | c.698G>T p.R233M | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV53066890, COSV99522443; called by muse, mutect2, varscan2
- NCKAP5 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58437689, COSV58437876; called by muse, mutect2, varscan2
- NES | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63960712; called by muse, mutect2, varscan2
- NKX2-4 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV61085075; called by muse, mutect2, varscan2
- NOTCH1 | c.2930G>A p.G977E | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759897410, COSV53042877; called by muse, mutect2, varscan2
- NPAP1 | c.2713G>C p.D905H | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as COSV61505949; called by muse, mutect2, varscan2
- NRXN1 | c.4147G>T p.G1383C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.923); catalogued as CM124773, COSV60492864; called by muse, mutect2, varscan2
- NTM | c.1009G>T p.V337F | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV66204184; called by muse, mutect2, varscan2
- OR10H5 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as COSV58277824; called by muse, mutect2, varscan2
- OR10W1 | c.833C>A p.P278Q | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67720346; called by muse, mutect2, varscan2
- OR10X1 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV63767217; called by muse, mutect2, varscan2
- OR14I1 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV61199357; called by muse, mutect2, varscan2
- OR2M2 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 117/911 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV62898119; called by muse, mutect2, varscan2
- OR2T12 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 175/308 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1558277031, COSV58777054; called by muse, mutect2, varscan2
- OR2T33 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); catalogued as COSV58814979, COSV58817980; called by muse, mutect2, varscan2
- OR4C46 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60218840; called by muse, mutect2, varscan2
- OR4K1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs543752160, COSV53458720, COSV99579378; called by muse, mutect2, varscan2
- OR4N2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 144/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1382697468, COSV60050828; called by muse, mutect2
- OR5M3 | c.876C>A p.N292K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs962696572, COSV56566357; called by muse, mutect2, varscan2
- OR5M3 | c.875A>C p.N292T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56566364; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 191/320 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2, varscan2
- PAK4 | c.1771A>T p.R591* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as COSV58944602; called by muse, mutect2, varscan2
- PAK5 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 111/350 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs924744761, COSV62025010; called by muse, mutect2, varscan2
- PCSK2 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.362); catalogued as COSV52730032; called by muse, mutect2, varscan2
- PDS5A | c.3695G>A p.S1232N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV57824498; called by muse, mutect2
- PEG3 | c.3769C>A p.Q1257K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV55630162; called by muse, mutect2, varscan2
- PEG3 | c.3343G>T p.G1115C | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55630172, COSV55642967; called by muse, mutect2, varscan2
- PHF3 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as COSV50316064; called by muse, mutect2, varscan2
- PIK3R4 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63240182, COSV63240700; called by muse, mutect2, varscan2
- PLCL2 | c.2631C>G p.H877Q (on ENST00000615277 / NM_001144382.2; = p.H751Q on NM_015184.5) | Missense Mutation (SNP) | VAF 91/131 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140113907, COSV67623974; called by muse, mutect2, varscan2
- PLEC | c.3736G>A p.E1246K (on ENST00000322810 / NM_201380.4; = p.E1136K on NM_000445.5) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782316766, COSV59623432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLTP | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.465); catalogued as COSV51941613, COSV51943282; called by muse, mutect2, varscan2
- PMEL | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59385490; called by muse, mutect2, varscan2
- PMF1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771971437, COSV60771389; called by muse, mutect2, varscan2
- PRDM16 | c.2852A>G p.Y951C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54586527; called by muse, mutect2, varscan2
- PRPF19 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 63/151 reads (42%) | catalogued as COSV57127467, COSV57129658; called by muse, mutect2, varscan2
- PRR35 | c.1283C>A p.A428E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.142); catalogued as COSV53461764, COSV53462424; called by muse, mutect2, varscan2
- PTPRG | c.354A>C p.K118N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV55635873; called by muse, mutect2, varscan2
- PTPRS | c.4636G>A p.E1546K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs776015928, COSV53616196; called by muse, mutect2, varscan2
- RAD21 | c.1786A>G p.K596E | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52057957; called by muse, mutect2
- RBAK | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 76/95 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV62331185; called by muse, mutect2, varscan2
- RBM8A | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 91/152 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.206); catalogued as COSV57162194; called by muse, mutect2, varscan2
- RELN | c.4927G>A p.E1643K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); catalogued as rs1232903628, COSV58995260; called by muse, mutect2
- RFC5 | c.823T>A p.L275M | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV57477222; called by muse, mutect2, varscan2
- RLN3 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV54600067; called by muse, mutect2, varscan2
- ROBO4 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100127322; called by muse, varscan2
- ROPN1 | c.623G>T p.R208M | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV51739563; called by muse, mutect2, varscan2
- RXRA | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62684014, COSV62684022; called by muse, mutect2, varscan2
- RYR2 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs886046261, COSV63677348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4F | c.124A>T p.R42* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV60282885; called by muse, mutect2, varscan2
- SEMA6D | c.2452C>T p.P818S (on ENST00000316364 / NM_153618.2; = p.P756S on NM_020858.2) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV60375303; called by muse, mutect2, varscan2
- SERPINB2 | c.924C>G p.Y308* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100208247, COSV55091857; called by muse, mutect2, varscan2
- SF3B4 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV54964958, COSV99641142; called by muse, mutect2, varscan2
- SLC14A1 | c.65T>A p.V22D | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58931514; called by muse, mutect2
- SLC17A7 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs1420335327, COSV55547286; called by muse, mutect2, varscan2
- SLC25A13 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 170/218 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55705623; called by muse, mutect2, varscan2
- SLC26A4 | c.2034+1G>A p.X678_splice | Splice Site (SNP) | VAF 44/53 reads (83%) | catalogued as rs759683649, COSV55915610; called by muse, mutect2, varscan2
- SMC6 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV61173279; called by muse, mutect2, varscan2
- SOGA1 | c.3679G>T p.A1227S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767541679, COSV52915792; called by muse, mutect2, varscan2
- SOS1 | c.3149T>C p.M1050T | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV67674687; called by muse, mutect2, varscan2
- STC1 | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV51688206, COSV99282444; called by muse, mutect2, varscan2
- STK3 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV69222885; called by muse, mutect2, varscan2
- SYCP1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 57/90 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65694390, COSV65696392; called by muse, mutect2, varscan2
- SYNE1 | c.15371T>A p.L5124* (on ENST00000367255 / NM_182961.4; = p.L5053* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 31/45 reads (69%) | catalogued as COSV54952637; called by muse, mutect2, varscan2
- TBX18 | c.1617A>T p.K539N | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV63736555; called by muse, mutect2, varscan2
- TCL1A | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs895880547, COSV68085089; called by muse, mutect2, varscan2
- TECTA | c.6461C>A p.T2154N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV50699446; called by muse, mutect2, varscan2
- TMEM74B | c.765G>T p.R255S | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67891838; called by muse, mutect2, varscan2
- TNKS | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV60055134; called by muse, mutect2, varscan2
- TPSD1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 25/149 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV52974913; called by muse, mutect2, varscan2
- TPTE | c.464C>T p.S155F (on ENST00000618007 / NM_199261.4; = p.S137F on NM_199259.4) | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753473286; called by muse, mutect2
- TRAF1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV65868168; called by muse, mutect2, varscan2
- TRIM51 | c.761G>T p.R254M | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV55265580; called by muse, mutect2, varscan2
- TRPC1 | c.1499G>T p.G500V (on ENST00000476941 / NM_001251845.2; = p.G466V on NM_003304.4) | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV56424197; called by muse, mutect2, varscan2
- TSSK2 | c.707C>A p.P236Q | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52816675; called by muse, mutect2, varscan2
- TTC21B | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV54629369; called by muse, mutect2
- TTN | c.64249A>T p.T21417S (on ENST00000591111; = p.T13993S on NM_003319.4) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | PolyPhen possibly damaging (0.637); catalogued as rs752304059, COSV59981751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.27403G>A p.A9135T (on ENST00000591111; = p.A8208T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/188 reads (35%) | PolyPhen benign (0.017); catalogued as rs527663092, COSV59981782, COSV60306473; called by muse, mutect2, varscan2
- TTN | c.14924C>T p.P4975L (on ENST00000591111; = p.P4048L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/293 reads (37%) | PolyPhen benign (0.013); catalogued as rs1394563400, COSV59981794; called by muse, mutect2, varscan2
- TTN | c.1541G>T p.R514I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | PolyPhen probably damaging (0.983); catalogued as rs139178471, COSV59914412; called by muse, mutect2, varscan2
- USH2A | c.5856A>C p.A1952= | Splice Region (SNP) | VAF 170/284 reads (60%) | catalogued as COSV56353220; called by muse, mutect2, varscan2
- USP46 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV71512716; called by muse, mutect2
- VAT1L | c.941C>A p.A314E | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56816049, COSV56817510; called by muse, mutect2, varscan2
- VDR | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV57467694; called by muse, mutect2, varscan2
- VN1R4 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60804838; called by muse, mutect2, varscan2
- VNN2 | c.1561T>C p.*521Qext*28 | Nonstop Mutation (SNP) | VAF 47/64 reads (73%) | catalogued as rs781378674, COSV58472180; called by muse, mutect2, varscan2
- VPS13A | c.5882G>C p.R1961P | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62427655; called by muse, mutect2
- XKR4 | c.413T>A p.L138Q | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV59306971, COSV59309362; called by muse, mutect2, varscan2
- ZBBX | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV56786731; called by muse, mutect2, varscan2
- ZFP42 | c.923A>G p.E308G | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs775355959, COSV58816971; called by muse, mutect2, varscan2
- ZNF160 | c.961del p.V321Sfs*36 | Frame Shift Del (DEL) | VAF 64/159 reads (40%) | catalogued as COSV100762336; called by mutect2, pindel, varscan2
- ZNF257 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV71306668; called by muse, mutect2, varscan2
- ZNF285 | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58408555; called by muse, mutect2, varscan2
- ZNF286A | c.477A>T p.E159D | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67845379; called by muse, mutect2, varscan2
- ZNF461 | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64453370; called by muse, mutect2, varscan2
- ZNF483 | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58515204; called by muse, mutect2, varscan2
- ZNF519 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV73913279, COSV73913372; called by muse, mutect2, varscan2
- ZNF566 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67573543; called by muse, mutect2, varscan2
- ZNF626 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV74129271; called by muse, mutect2, varscan2
- ZNF675 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63095651; called by muse, mutect2, varscan2
- ZNF804A | c.2837A>T p.N946I | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV56443205; called by muse, mutect2, varscan2
- ADAM22 | c.1506_1520del p.C503_V507del | In Frame Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- COL25A1 | c.1201del p.D401Ifs*29 | Frame Shift Del (DEL) | VAF 27/58 reads (47%) | called by mutect2, pindel, varscan2
- EPHA5 | c.489del p.R164Efs*30 | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | called by mutect2, pindel, varscan2
- GCNT2 | c.585del p.L197* | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.242del p.P81Hfs*? | Frame Shift Del (DEL) | VAF 86/289 reads (30%) | called by mutect2, pindel, varscan2
- IGKV3-20 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- KIF23 | c.429_433del p.G144Ifs*4 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- KIR2DL4 | c.121T>C p.S41P (on ENST00000396284; = p.S2P on NM_001080770.2) | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NOTCH3 | c.747del p.T250Hfs*122 | Frame Shift Del (DEL) | VAF 37/107 reads (35%) | called by mutect2, pindel, varscan2
- RACGAP1 | c.1237del p.D413Mfs*10 | Frame Shift Del (DEL) | VAF 86/253 reads (34%) | called by mutect2, pindel, varscan2
- SAGE1 | c.1103del p.P368Qfs*14 | Frame Shift Del (DEL) | VAF 82/147 reads (56%) | called by mutect2, pindel, varscan2
- SHANK1 | c.4904C>T p.T1635I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by mutect2, varscan2
- BCL9L | c.4029C>T p.P1343= | Silent (SNP) | VAF 73/184 reads (40%) | catalogued as COSV52683354; called by muse, mutect2
- BPIFA3 | c.51G>A p.L17= | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as rs778425801, COSV64925739; called by muse, mutect2, varscan2
- BRCA1 | c.1227A>T p.V409= | Silent (SNP) | VAF 64/201 reads (32%) | catalogued as COSV58787779; called by muse, mutect2, varscan2
- BTK | c.621A>G p.A207= | Silent (SNP) | VAF 79/96 reads (82%) | catalogued as rs782252504, COSV58118675; called by muse, mutect2, varscan2
- CEACAM21 | c.561G>A p.T187= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1241267641, COSV51813673; called by muse, mutect2, varscan2
- CHRM4 | c.1419G>A p.R473= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1047515780, COSV58987050; called by muse, mutect2, varscan2
- CHRNG | c.1408C>A p.R470= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as CM062515, COSV51471239; called by muse, mutect2, varscan2
- CLEC4M | c.147C>T p.G49= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as rs539558959, COSV50217604; called by muse, mutect2, varscan2
- COX10 | c.48C>T p.C16= | Silent (SNP) | VAF 68/193 reads (35%) | catalogued as rs748889500, COSV55404140; ClinVar: benign; called by muse, mutect2, varscan2
- CSMD3 | c.3573T>C p.G1191= (on ENST00000297405 / NM_001363185.1; = p.G1087= on NM_052900.3) | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV52148059; called by muse, mutect2, varscan2
- CTNNA2 | c.237T>A p.A79= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV63558329; called by muse, mutect2, varscan2
- CXCR4 | c.238C>T p.L80= | Silent (SNP) | VAF 15/254 reads (6%) | catalogued as COSV54011480; called by muse, mutect2
- CYFIP1 | c.1092G>C p.A364= | Silent (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- DENND4A | c.4314C>T p.F1438= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as COSV71265575; called by muse, mutect2, varscan2
- DLX2 | c.180C>A p.T60= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs943711501, COSV52231900; called by muse, mutect2, varscan2
- EFHD1 | c.675C>G p.L225= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV51132183; called by muse, mutect2, varscan2
- FLI1 | c.348C>T p.N116= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs376782867, COSV55643772; called by muse, mutect2, varscan2
- FREM1 | c.4467G>T p.R1489= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV66521466, COSV66529981; called by muse, mutect2, varscan2
- FTL | c.51C>G p.V17= | Silent (SNP) | VAF 55/175 reads (31%) | catalogued as COSV53169774; called by muse, mutect2, varscan2
- GGTLC1 | c.156C>A p.A52= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV53847212; called by muse, varscan2
- GNPTG | c.606C>A p.P202= | Silent (SNP) | VAF 38/51 reads (75%) | catalogued as COSV50189902; called by muse, mutect2, varscan2
- GUCY1A2 | c.927C>A p.T309= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV56483262; called by muse, mutect2, varscan2
- INPP5B | c.219G>T p.V73= | Silent (SNP) | VAF 61/90 reads (68%) | catalogued as COSV65957945; called by muse, mutect2, varscan2
- KCTD14 | c.618G>C p.A206= | Silent (SNP) | VAF 89/222 reads (40%) | catalogued as rs376094397, COSV62001066, COSV62001309; called by muse, mutect2, varscan2
- KLHL32 | c.816T>C p.Y272= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs760642211, COSV65111509; called by muse, mutect2, varscan2
- LAIR1 | c.723G>T p.L241= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as COSV57307044; called by muse, mutect2, varscan2
- LILRA2 | c.576G>A p.S192= | Silent (SNP) | VAF 38/320 reads (12%) | catalogued as rs763571960, COSV52190338; called by muse, mutect2, varscan2
- LILRB2 | c.1230C>T p.P410= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as COSV100078830, COSV58744441; called by muse, mutect2, varscan2
- LIPE | c.1944G>T p.V648= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV54922202; called by muse, mutect2, varscan2
- MYH15 | c.1779T>C p.H593= | Silent (SNP) | VAF 212/284 reads (75%) | catalogued as COSV56307791; called by muse, mutect2, varscan2
- NKG7 | c.497G>A p.*166= | Silent (SNP) | VAF 149/537 reads (28%) | catalogued as rs560680752, COSV52467340, COSV52467447; called by muse, mutect2, varscan2
- NME8 | c.657T>C p.S219= | Silent (SNP) | VAF 129/154 reads (84%) | catalogued as COSV52248889; called by muse, mutect2, varscan2
- NTRK1 | c.1743G>A p.E581= | Silent (SNP) | VAF 70/118 reads (59%) | catalogued as rs138423540, COSV62324807; called by muse, mutect2, varscan2
- NUCB1 | c.1071G>C p.R357= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV54385885, COSV54386870; called by muse, mutect2, varscan2
- OR2G2 | c.579G>T p.V193= | Silent (SNP) | VAF 93/356 reads (26%) | catalogued as COSV60740074; called by muse, mutect2, varscan2
- OR4A5 | c.819C>G p.T273= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs765786103, COSV60522150; called by muse, mutect2, varscan2
- OR4F6 | c.117G>T p.L39= | Silent (SNP) | VAF 132/459 reads (29%) | catalogued as COSV100187023, COSV61026574; called by muse, mutect2, varscan2
- OSR1 | c.168G>C p.T56= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV55345066, COSV55346449; called by muse, mutect2, varscan2
- PDZD2 | c.7389G>A p.K2463= | Silent (SNP) | VAF 10/328 reads (3%) | catalogued as COSV56855572; called by muse, mutect2
- PIP5K1B | c.333T>C p.S111= | Silent (SNP) | VAF 84/210 reads (40%) | catalogued as COSV55245427; called by muse, mutect2, varscan2
- PRDM14 | c.216G>T p.R72= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV52571580; called by muse, mutect2, varscan2
- PRX | c.885G>T p.V295= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV52529054; called by muse, mutect2, varscan2
- SLC35F1 | c.375A>G p.L125= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV64501564; called by muse, mutect2, varscan2
- SLC8B1 | c.681G>T p.L227= | Silent (SNP) | VAF 120/316 reads (38%) | catalogued as COSV52527236; called by muse, mutect2, varscan2
- SRGAP2 | c.2886G>A p.Q962= (on ENST00000624873 / NM_001170637.4; = p.Q963= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV55335646, COSV55343423; called by muse, mutect2, varscan2
- SSTR4 | c.873C>A p.T291= | Silent (SNP) | VAF 60/182 reads (33%) | catalogued as rs199944012, COSV54798018, COSV99658371; called by muse, mutect2
- STEAP4 | c.795T>C p.A265= | Silent (SNP) | VAF 91/106 reads (86%) | catalogued as COSV57328851; called by muse, mutect2, varscan2
- TCN1 | c.1230A>G p.P410= | Silent (SNP) | VAF 224/586 reads (38%) | catalogued as COSV57252776; called by muse, mutect2, varscan2
- TNR | c.3114T>G p.S1038= | Silent (SNP) | VAF 81/328 reads (25%) | catalogued as COSV54879073; called by muse, mutect2, varscan2
- TRMT2A | c.1200G>C p.L400= | Silent (SNP) | VAF 74/259 reads (29%) | catalogued as COSV52813033; called by muse, mutect2, varscan2
- TSGA10IP | c.1174C>A p.R392= | Silent (SNP) | VAF 96/204 reads (47%) | catalogued as COSV73245200, COSV73245257; called by muse, mutect2, varscan2
- UNC13C | c.3927G>T p.L1309= | Silent (SNP) | VAF 91/212 reads (43%) | catalogued as COSV52860421; called by mutect2, varscan2
- ZC3H13 | c.2904G>A p.K968= | Silent (SNP) | VAF 40/349 reads (11%) | catalogued as COSV99667548; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3863del | 3'UTR (DEL) | VAF 90/302 reads (30%) | called by mutect2, pindel, varscan2
- DCHS2 | n.7646G>T | RNA (SNP) | VAF 27/39 reads (69%) | catalogued as COSV61770083; called by muse, mutect2, varscan2
- KALRN | c.4929+22030del | Intron (DEL) | VAF 42/319 reads (13%) | called by mutect2, pindel, varscan2
- MIR663B | n.66G>T | RNA (SNP) | VAF 15/45 reads (33%) | catalogued as rs769041029; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43300622 A>T | 5'Flank (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.74G>T | RNA (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- TPSD1 | c.-1G>A | 5'UTR (SNP) | VAF 26/148 reads (18%) | catalogued as rs762590630, COSV99273638; called by muse, mutect2, varscan2
